Somatic mutation profile of tumor specimen TCGA-22-4609-01A (aliquot TCGA-22-4609-01A-21D-2122-08) from TCGA case TCGA-22-4609, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 81.7 years (29,844 days).
Specimen TCGA-22-4609-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79730ee9-58c6-48f1-ab38-8db26eb2dc77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-4609-11A (Solid Tissue Normal), aliquot TCGA-22-4609-11A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92afb716-8e79-410b-9ba8-e429af918758

The open-access MAF lists 215 somatic variants for this specimen: 156 protein-altering or splice-affecting, 50 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, Silent 50, Nonsense Mutation 9, Splice Site 3, RNA 3, Splice Region 3, Intron 3, 3'Flank 3, Frame Shift Ins 2, Frame Shift Del 2, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as rs1369857952, COSV101201105; called by muse, mutect2, varscan2
- ACER3 | c.597G>A p.L199= | Splice Region (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99568176; called by muse, varscan2
- ACSBG1 | c.2150C>A p.S717Y | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV99357284; called by muse, mutect2
- ACSBG1 | c.2149T>A p.S717T | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV99357286; called by muse, mutect2
- ACSM1 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99532812; called by muse, mutect2, varscan2
- ACSM5 | c.1001+1G>T p.X334_splice | Splice Site (SNP) | VAF 39/195 reads (20%) | catalogued as COSV100088752; called by muse, mutect2, varscan2
- ACSM5 | c.1698G>T p.K566N | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100088754; called by muse, mutect2, varscan2
- ADAMTS13 | c.3133G>A p.G1045S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs782789479, COSV100747034; called by muse, mutect2, varscan2
- ALAS2 | c.803C>T p.T268I | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100238176; called by mutect2, varscan2
- ALG5 | c.496G>T p.G166* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as COSV99523601; called by muse, mutect2, varscan2
- AMER3 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100366359; called by muse, mutect2, varscan2
- AMMECR1L | c.920A>G p.N307S | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.338); catalogued as rs751024861, COSV55761257; called by muse, mutect2, varscan2
- ANKRD44 | c.797A>T p.N266I | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99984686; called by muse, mutect2, varscan2
- AQR | c.4015C>T p.P1339S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV50029467, COSV99333724; called by muse, mutect2, varscan2
- ARHGAP5 | c.4409G>C p.G1470A (on ENST00000345122 / NM_001030055.2; = p.G1469A on NM_001173.3) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as COSV99391935; called by muse, mutect2, varscan2
- ASNSD1 | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99641119; called by muse, mutect2, varscan2
- ASTN1 | c.3443T>C p.V1148A | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1159380568, COSV100706208; called by muse, mutect2, varscan2
- ASTN1 | c.1576C>T p.Q526* | Nonsense Mutation (SNP) | VAF 29/114 reads (25%) | catalogued as COSV56080674, COSV99921171; called by muse, mutect2, varscan2
- ATP1A2 | c.2129C>A p.A710D | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100767760, COSV63402846; called by muse, mutect2, varscan2
- ATP4A | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99382434; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV100376956; called by muse, mutect2, varscan2
- ATXN10 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV99426228; called by muse, mutect2, varscan2
- C6orf118 | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.39); catalogued as COSV100024354; called by muse, mutect2
- CCNL1 | c.1516G>C p.E506Q | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); catalogued as COSV99904469; called by muse, mutect2, varscan2
- CLSTN3 | c.1915G>T p.D639Y | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV56936479, COSV99866843; called by muse, mutect2, varscan2
- CNTNAP2 | c.401G>T p.W134L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as rs1458942108, COSV62141132; called by muse, mutect2, varscan2
- COL22A1 | c.3707C>A p.P1236H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs767926222, COSV100277742; called by muse, mutect2, varscan2
- COL22A1 | c.16G>T p.G6W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV57331570; called by muse, mutect2, varscan2
- COQ4 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100306693; called by muse, mutect2
- CPB1 | c.266A>C p.Q89P | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs776604667, COSV99294190; called by muse, mutect2, varscan2
- CR1L | c.890A>T p.H297L | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99687116; called by muse, mutect2, varscan2
- CSMD1 | c.6119C>A p.P2040H (on ENST00000520002; = p.P2039H on NM_033225.6) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV100146679; called by muse, mutect2, varscan2
- CTNNA2 | c.2675A>T p.K892M (on ENST00000402739 / NM_001282597.3; = p.K844M on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100560076; called by muse, mutect2, varscan2
- CWH43 | c.1356C>A p.H452Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99893234; called by muse, mutect2, varscan2
- DAGLA | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV99944268; called by muse, mutect2, varscan2
- DCTN5 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs768348316, COSV100265934; called by muse, mutect2, varscan2
- DDX4 | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61755927; called by muse, mutect2, varscan2
- DFFB | c.511-1G>A p.X171_splice | Splice Site (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100138651; called by muse, mutect2, varscan2
- DNAH3 | c.5141G>A p.G1714D | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV99766517; called by muse, mutect2, varscan2
- DNAJB12 | c.944G>A p.G315D (on ENST00000338820; = p.G281D on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100123741; called by muse, mutect2, varscan2
- DPP10 | c.259C>G p.R87G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV100062581, COSV59677730; called by muse, mutect2
- EPAS1 | c.2527G>T p.D843Y | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763106; called by muse, mutect2, varscan2
- EPB41L2 | c.1147A>T p.R383W | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100440537; called by muse, mutect2, varscan2
- ESYT2 | c.1184A>T p.Q395L (on ENST00000613624; = p.Q319L on NM_020728.3) | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV51750383, COSV99276583; called by muse, mutect2, varscan2
- EXPH5 | c.74T>G p.L25R | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99761387; called by muse, mutect2, varscan2
- FAM47A | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as COSV60499460; called by muse, mutect2, varscan2
- FOCAD | c.3775T>A p.W1259R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100620287; called by muse, mutect2, varscan2
- FRY | c.4449C>A p.C1483* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100969085, COSV66577081; called by muse, mutect2, varscan2
- GABRR1 | c.171C>T p.V57= | Splice Region (SNP) | VAF 21/133 reads (16%) | catalogued as rs1271832206, COSV101033847; called by muse, mutect2, varscan2
- GALNT7 | c.1297G>T p.V433F | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99397226; called by muse, mutect2, varscan2
- GASK1B | c.57C>G p.C19W | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV99647530; called by muse, mutect2, varscan2
- GOLGB1 | c.9007G>T p.V3003L | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100510671; called by muse, mutect2, varscan2
- GPAM | c.1505T>A p.L502H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100788172; called by muse, mutect2, varscan2
- GPD1L | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV99245647; called by muse, mutect2, varscan2
- GRM5 | c.1392A>C p.G464= | Splice Region (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100551351, COSV59610194; called by muse, mutect2, varscan2
- HECTD4 | c.7528G>T p.G2510C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101107249; called by muse, mutect2, varscan2
- HHAT | c.514A>G p.T172A | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as COSV99803653; called by muse, mutect2, varscan2
- IFI44 | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1420634329, COSV66074470; called by muse, mutect2, varscan2
- INVS | c.2743A>G p.K915E | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV99317384; called by muse, mutect2, varscan2
- ITGA2 | c.1522G>T p.V508L | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.132); catalogued as COSV56862984, COSV99669948; called by muse, mutect2, varscan2
- KCNA4 | c.1349G>C p.R450P | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068829; called by muse, mutect2, varscan2
- KRT13 | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99877319; called by muse, mutect2, varscan2
- KRTAP5-3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs571662260, COSV101294499, COSV68790920; called by muse, varscan2
- LHX9 | c.536G>T p.S179I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.555); catalogued as COSV100435792; called by muse, mutect2, varscan2
- LRP1B | c.1790-1G>T p.X597_splice | Splice Site (SNP) | VAF 19/78 reads (24%) | catalogued as COSV101255389; called by muse, mutect2, varscan2
- LRRK2 | c.3818T>A p.L1273Q | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100109847; called by muse, mutect2, varscan2
- LTV1 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs924212185, COSV100849568; called by muse, mutect2, varscan2
- MAGEL2 | c.2480G>T p.C827F | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV100045880; called by muse, mutect2, varscan2
- MAGI1 | c.4208G>A p.R1403H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.385); catalogued as rs763951532, COSV100440398; called by muse, mutect2, varscan2
- MARCHF1 | c.648C>G p.Y216* (on ENST00000274056; = p.Y199* on NM_017923.4) | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99920636; called by muse, mutect2, varscan2
- MICU2 | c.1034T>C p.V345A | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV101212430; called by muse, varscan2
- MINAR1 | c.1657A>T p.K553* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100548831; called by muse, mutect2, varscan2
- MSANTD4 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs769889206, COSV57286539; called by muse, mutect2, varscan2
- MYH13 | c.2730A>T p.E910D | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV52830644; called by muse, mutect2, varscan2
- MYH2 | c.1400G>T p.G467V | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99819898; called by muse, mutect2, varscan2
- MYRF | c.1642G>C p.A548P (on ENST00000278836 / NM_001127392.3; = p.A539P on NM_013279.4) | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV53892269, COSV99606899; called by muse, mutect2, varscan2
- MYT1L | c.3193C>G p.Q1065E | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs1558596910, COSV101217053; called by muse, mutect2, varscan2
- NAV1 | c.2005C>A p.Q669K | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99818621; called by muse, mutect2, varscan2
- NAV1 | c.3865C>T p.P1289S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99818623; called by muse, mutect2, varscan2
- NCAM2 | c.1477G>T p.A493S | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99522565; called by muse, mutect2, varscan2
- NDN | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs1444928115, COSV100086397; called by muse, mutect2, varscan2
- NOTCH4 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100900602, COSV66679443; called by muse, mutect2, varscan2
- NPHS1 | c.3515C>A p.P1172H | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV100799750; called by muse, mutect2, varscan2
- NSDHL | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM156197, COSV100938644; called by muse, mutect2, varscan2
- OR4K2 | c.945G>C p.*315Yext*3 | Nonstop Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100064330, COSV100064352; called by muse, mutect2, varscan2
- OR4K5 | c.45G>C p.L15F | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as COSV100262438; called by muse, mutect2, varscan2
- OR4X1 | c.874G>T p.V292L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs780850758, COSV100186635; called by muse, mutect2
- OR52A5 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV100263385; called by muse, mutect2, varscan2
- OR5D16 | c.635C>A p.T212K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101003913; called by muse, mutect2, varscan2
- OR5W2 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100747593; called by muse, mutect2
- PALM2AKAP2 | c.203G>T p.R68M (on ENST00000374531 / NM_001037293.2; = p.R66M on NM_007203.5) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); catalogued as COSV57130348; called by muse, mutect2, varscan2
- PAX7 | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV64750609; called by muse, mutect2, varscan2
- PCDH11X | c.1457C>T p.T486M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs62621113, COSV53445288, COSV53466454; called by muse, mutect2
- PDE2A | c.2348T>C p.M783T | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100557843; called by muse, mutect2, varscan2
- PGA5 | c.1140C>A p.N380K | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV100409288; called by muse, mutect2, varscan2
- PKHD1L1 | c.11815T>C p.F3939L | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs760677348, COSV101005958; called by muse, mutect2, varscan2
- PLEKHG4 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as COSV100846474; called by muse, mutect2
- POLE | c.3614C>T p.P1205L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs772686048, COSV57682027; ClinVar: uncertain significance; called by muse, mutect2
- PPP1CC | c.547A>G p.M183V | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.051); catalogued as rs1354858476, COSV100534826; called by muse, mutect2, varscan2
- PRDM14 | c.1069C>G p.H357D | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.085); catalogued as COSV99400058; called by muse, mutect2, varscan2
- PRDM9 | c.263C>A p.T88K | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as COSV57010640, COSV99690254; called by muse, mutect2, varscan2
- PRMT1 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV101212259; called by muse, varscan2
- PTPN5 | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100079541; called by muse, mutect2, varscan2
- PTPRC | c.962T>A p.I321N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100722479, COSV61410993; called by mutect2, varscan2
- RASA3 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV100480345; called by muse, mutect2
- RNF112 | c.907A>T p.K303* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as COSV101465404; called by muse, mutect2, varscan2
- RYR2 | c.14696A>T p.D4899V | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100769507; called by muse, mutect2, varscan2
- SAMD15 | c.391A>G p.K131E | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780097668, COSV99374901; called by muse, mutect2, varscan2
- SATB1 | c.2082G>C p.Q694H | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100113084, COSV58669124; called by muse, mutect2, varscan2
- SH2D3C | c.769C>T p.R257C (on ENST00000314830 / NM_170600.3; = p.R100C on NM_005489.4) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs754838736, COSV100136751; called by muse, mutect2, varscan2
- SIGLECL1 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV100323901; called by muse, mutect2, varscan2
- SLC24A1 | c.119A>G p.H40R | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as rs1429541732, COSV99978188; called by muse, mutect2, varscan2
- SLC25A12 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as rs770856651, COSV55532728; called by muse, mutect2, varscan2
- SLC35F1 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100837482; called by muse, mutect2, varscan2
- SLC5A4 | c.1197C>A p.N399K | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99831852; called by muse, mutect2, varscan2
- SLITRK6 | c.1331A>T p.Y444F | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV101233212; called by muse, mutect2, varscan2
- SOGA3 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.034); catalogued as COSV100846722; called by mutect2, varscan2
- SPATA18 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV99730396; called by muse, mutect2
- STK33 | c.455C>A p.A152D | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100173901; called by muse, mutect2, varscan2
- TBC1D4 | c.2244G>T p.R748S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); catalogued as COSV100884574; called by muse, mutect2, varscan2
- TBCK | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV99912388; called by muse, mutect2, varscan2
- TBX4 | c.1382A>T p.Q461L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV99540097; called by muse, mutect2, varscan2
- THBS3 | c.584T>C p.M195T | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV100366792; called by muse, mutect2, varscan2
- THSD7A | c.2532A>T p.Q844H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV101448645; called by muse, mutect2, varscan2
- TIGD2 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.893); catalogued as COSV100392328; called by muse, mutect2, varscan2
- TMEM202 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV100499137; called by muse, mutect2, varscan2
- TP53 | c.192del p.R65Efs*58 | Frame Shift Del (DEL) | VAF 40/203 reads (20%) | catalogued as CD065798; called by mutect2, pindel, varscan2
- TRDN | c.2120C>T p.T707I | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1327844932, COSV100521628; called by muse, mutect2
- TRNT1 | c.838A>G p.K280E | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV99214141; called by muse, mutect2, varscan2
- TRPC3 | c.551G>T p.S184I (on ENST00000379645 / NM_001366479.2; = p.S111I on NM_003305.2) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99312468; called by muse, mutect2, varscan2
- TRPC7 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs757044773, COSV100725655, COSV61452956; called by muse, mutect2, varscan2
- TRPM2 | c.3799G>T p.E1267* | Nonsense Mutation (SNP) | VAF 50/127 reads (39%) | catalogued as COSV100308590; called by muse, mutect2, varscan2
- TSLP | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1051937084, COSV100789177; called by muse, mutect2, varscan2
- TTN | c.87137G>C p.G29046A (on ENST00000591111; = p.G21622A on NM_003319.4) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | PolyPhen probably damaging (0.975); catalogued as COSV100605660, COSV60040815; called by muse, mutect2, varscan2
- TTN | c.49283C>A p.P16428Q (on ENST00000591111; = p.P9004Q on NM_003319.4) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | PolyPhen probably damaging (0.999); catalogued as COSV100605670; called by muse, mutect2, varscan2
- UTP20 | c.2458T>G p.F820V | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99881379; called by muse, mutect2, varscan2
- WDR59 | c.1999A>T p.I667L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100049168; called by muse, mutect2, varscan2
- WIZ | c.2569A>G p.I857V (on ENST00000673675 / NM_001371589.1; = p.I120V on NM_021241.3) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as COSV99653020; called by muse, mutect2, varscan2
- WNK2 | c.3103G>A p.V1035I | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.972); catalogued as rs545534825, COSV99941901; called by muse, mutect2, varscan2
- XRRA1 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100369763, COSV58500933; called by muse, mutect2, varscan2
- XYLT1 | c.1694A>G p.Y565C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99761267; called by muse, mutect2, varscan2
- ZC3H13 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as COSV99667936; called by muse, mutect2, varscan2
- ZFHX4 | c.2210A>C p.Q737P | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99261323; called by muse, mutect2, varscan2
- ZNF266 | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as COSV100749370; called by muse, mutect2, varscan2
- ZNF570 | c.1568A>C p.E523A | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV100356125; called by muse, mutect2, varscan2
- ZNF619 | c.1077A>T p.K359N | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.864); catalogued as COSV59030865; called by muse, mutect2, varscan2
- ZNF691 | c.395C>A p.T132K (on ENST00000372502; = p.T101K on NM_015911.3) | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.186); catalogued as COSV100996076; called by muse, mutect2, varscan2
- CECR2 | c.3221_3234del p.E1074Gfs*15 (on ENST00000342247 / NM_001290047.2; = p.E890Gfs*15 on NM_001290046.1) | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- KIFC2 | c.1795dup p.R599Pfs*221 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- MUC17 | c.716C>G p.T239S | Missense Mutation (SNP) | VAF 11/326 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, mutect2
- NCKAP5L | c.2665_2688del p.K889_L896del | In Frame Del (DEL) | VAF 14/79 reads (18%) | called by mutect2, pindel
- NPY1R | c.1091dup p.L364Ffs*10 | Frame Shift Ins (INS) | VAF 32/165 reads (19%) | called by mutect2, pindel, varscan2
- TRAV17 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- TRAV38-2DV8 | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- UPB1 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, varscan2
- VN1R5 | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ADAMTS2 | c.3174G>T p.S1058= | Silent (SNP) | VAF 49/227 reads (22%) | catalogued as COSV52393988, COSV99281745; called by muse, mutect2, varscan2
- ATAD2 | c.2115G>A p.V705= | Silent (SNP) | VAF 42/123 reads (34%) | catalogued as rs779486498, COSV99784484; called by muse, mutect2, varscan2
- CCNA1 | c.747C>T p.D249= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV99714498; called by muse, mutect2, varscan2
- CD200R1 | c.75C>T p.S25= (on ENST00000471858 / NM_170780.3; = p.S48= on NM_138806.4) | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs1212206066, COSV99867088; called by muse, mutect2, varscan2
- CGB7 | c.252C>T p.F84= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as rs1398317801, COSV62282202; called by muse, mutect2, varscan2
- CHST11 | c.228C>G p.V76= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs754970863, COSV100359306; called by muse, mutect2, varscan2
- CLSTN3 | c.1914T>A p.P638= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV99866840; called by muse, mutect2, varscan2
- CPXCR1 | c.165A>T p.T55= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV99342118; called by muse, mutect2, varscan2
- CYRIB | c.753A>G p.S251= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV101309861; called by muse, mutect2, varscan2
- DGUOK | c.564C>T p.G188= | Silent (SNP) | VAF 50/285 reads (18%) | catalogued as COSV99903445; called by muse, mutect2, varscan2
- DNAH5 | c.11682G>T p.L3894= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as rs989347582, COSV99448343; called by muse, mutect2
- DZIP3 | c.2898A>G p.L966= | Silent (SNP) | VAF 41/277 reads (15%) | catalogued as COSV100847744; called by muse, mutect2, varscan2
- F2 | c.582G>T p.A194= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as COSV100319462; called by muse, mutect2, varscan2
- FMN2 | c.4759T>C p.L1587= | Silent (SNP) | VAF 26/176 reads (15%) | catalogued as COSV100144541, COSV60419697; called by muse, mutect2, varscan2
- FOXI1 | c.498C>T p.G166= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100089256; called by muse, mutect2, varscan2
- FREM2 | c.6507G>T p.G2169= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs376390031; called by muse, mutect2, varscan2
- GLIS1 | c.930C>T p.A310= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100389823; called by muse, mutect2, varscan2
- GMPS | c.240T>C p.S80= | Silent (SNP) | VAF 67/372 reads (18%) | catalogued as COSV99903063; called by muse, mutect2, varscan2
- GTF2E1 | c.1107G>T p.P369= | Silent (SNP) | VAF 25/148 reads (17%) | catalogued as COSV99381883; called by muse, mutect2, varscan2
- GUCY2C | c.772C>T p.L258= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as COSV99663515; called by muse, mutect2, varscan2
- HDAC4 | c.1689T>C p.I563= | Silent (SNP) | VAF 23/159 reads (14%) | catalogued as rs1402138710, COSV100613208; called by muse, mutect2, varscan2
- HMCN1 | c.6033C>A p.A2011= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as COSV99627647; called by muse, mutect2, varscan2
- KIF2B | c.616C>T p.L206= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV52137274, COSV99275153; called by muse, mutect2, varscan2
- KLK15 | c.591G>T p.A197= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as rs772908868, COSV100032462, COSV100032673; called by muse, mutect2, varscan2
- LMNTD1 | c.564T>A p.S188= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV99279649; called by muse, mutect2, varscan2
- MAPK1IP1L | c.195A>T p.G65= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as rs532978787, COSV101133265; called by muse, mutect2, varscan2
- MCM6 | c.2115A>G p.Q705= | Silent (SNP) | VAF 29/148 reads (20%) | catalogued as COSV99918933; called by muse, mutect2, varscan2
- MIA3 | c.321A>G p.E107= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100719405; called by muse, mutect2, varscan2
- MSRA | c.399G>T p.L133= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV100412771; called by muse, mutect2, varscan2
- NOS1 | c.198G>C p.A66= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs9658275; called by muse, mutect2, varscan2
- OR2L2 | c.609C>T p.T203= | Silent (SNP) | VAF 52/253 reads (21%) | catalogued as rs777839127, COSV100823431; called by muse, mutect2, varscan2
- OR2T8 | c.12G>T p.G4= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100178206; called by muse, mutect2, varscan2
- OR51Q1 | c.762C>T p.Y254= | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as rs1350454826, COSV100332888; called by muse, mutect2
- OR51T1 | c.51T>C p.T17= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as rs368143077; called by muse, mutect2, varscan2
- OR5F1 | c.330C>G p.T110= | Silent (SNP) | VAF 31/148 reads (21%) | catalogued as COSV53545530, COSV99558547; called by muse, mutect2, varscan2
- OR8H2 | c.906C>A p.I302= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV100542267; called by muse, mutect2, varscan2
- PARP14 | c.2778T>C p.F926= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV101506261; called by muse, mutect2, varscan2
- PGM5 | c.318C>T p.C106= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as rs781987584, COSV101123415; called by muse, varscan2
- PHF3 | c.5949A>G p.G1983= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100013188; called by muse, mutect2, varscan2
- PLXNA4 | c.5610C>T p.H1870= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs550735539, COSV100323719; called by mutect2, varscan2
- PRDM9 | c.264A>T p.T88= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as COSV99690255; called by muse, mutect2, varscan2
- PTPRU | c.3828C>T p.L1276= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100112376; called by muse, mutect2, varscan2
- RFTN2 | c.1293C>A p.I431= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as COSV99695493; called by muse, mutect2, varscan2
- SATB2 | c.2085G>T p.L695= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV99611036; called by muse, mutect2, varscan2
- SDCBP | c.244T>C p.L82= | Silent (SNP) | VAF 15/168 reads (9%) | catalogued as COSV99486249; called by muse, mutect2
- SLC18B1 | c.888T>C p.D296= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV99259049; called by muse, mutect2
- SLC4A8 | c.780T>A p.P260= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV100176685; called by muse, mutect2, varscan2
- SPAM1 | c.321A>T p.G107= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as COSV99772937; called by muse, mutect2, varscan2
- TTN | c.56280C>T p.S18760= (on ENST00000591111; = p.S11336= on NM_003319.4) | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as COSV100605667; called by muse, mutect2, varscan2
- UGT2B28 | c.1110T>C p.A370= | Silent (SNP) | VAF 46/173 reads (27%) | catalogued as COSV100158707; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827400 G>T | 3'Flank (SNP) | VAF 11/18 reads (61%) | called by muse, mutect2, varscan2
- C2orf83 | n.113G>T | RNA (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100018079; called by muse, mutect2, varscan2
- FADS1 | c.375+189G>T | Intron (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99952159; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397339 T>A | 3'Flank (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2
- MIR527 | n.83A>T | RNA (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2, varscan2
- OCLNP1 | n.184G>T | RNA (SNP) | VAF 5/11 reads (45%) | catalogued as rs757407987; called by mutect2, varscan2
- RNU6-1178P | chr17:20893415 C>A | 3'Flank (SNP) | VAF 9/51 reads (18%) | catalogued as rs1473999985, COSV100019056; called by muse, mutect2, varscan2
- SORCS1 | c.3371+178C>G | Intron (SNP) | VAF 27/100 reads (27%) | catalogued as COSV53914080, COSV99545311; called by muse, mutect2, varscan2
- VNN3 | c.345-2531C>A | Intron (SNP) | VAF 12/53 reads (23%) | catalogued as COSV99258223; called by muse, mutect2, varscan2
